Gene-level copy-number profile of tumor specimen ALCH-B35I-TTP1-A from ALCHEMIST case ALCH-B35I, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 57.5 years (20,989 days).
Specimen ALCH-B35I-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 7a00b4e5-4289-48c7-9993-8dfa292a6291.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-B35I-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/65f6ce16-8de8-433b-942e-2ad60bda01a0

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 48; copy number 1: 3,602; copy number 2: 54,886; copy number 3: 299; copy number 4: 62; copy number 5: 5; copy number 6: 3; copy number 20: 1.

Homozygous deletions (total copy number 0; autosomes only): 44 genes in 9 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:3,021,467–3,022,903, 1 gene: ACTRT2.
- chr1:5,478,736–5,494,674, 2 genes: Z98259.3, Z98259.1.
- chr2:89,266,494–89,600,680, 9 genes: IGKV1-33, IGKV3-34, IGKV1-35, IGKV2-36, IGKV1-37, IGKV2-38, IGKV1-39, IGKV2-40, 5S_rRNA.
- chr4:3,758,748–3,768,526, 2 genes: LINC02600, ADRA2C.
- chr5:135,038,831–135,040,047, 1 gene (within-gene range 0–1): C5orf66-AS1.
- chr7:62,275,361–62,275,678, 1 gene: AC128676.1.
- chr9:64,810,865–64,889,063, 4 genes: BNIP3P4, AL359955.1, AC125634.1, RNU6-1293P.
- chr15:25,199,448–25,204,438, 4 genes (within-gene range 0–2): SNORD115-16, SNORD115-17, SNORD115-18, SNORD115-19.
- chr15:25,218,617–25,257,027, 20 genes (within-gene range 0–2): SNORD115-26, SNORD115-27, SNORD115-28, SNORD115-29, SNORD115-30, SNORD115-31, SNORD115-32, SNORD115-33, SNORD115-34, SNORD115-35, SNORD115-36, SNORD115-37, SNORD115-38, SNORD115-39, SNORD115-40, SNORD115-41, SNORD115-42, SNORD115-43, SNORD115-44, AC124303.1.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 9 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr10:73,130,155–73,169,055, 1 gene, copy number 5 (within-gene range 3–5): ECD.
- chr15:58,865,006–58,865,303, 1 gene, copy number 20 (within-gene range 2–20): ZNF444P1.
- chr17:30,831,966–30,895,869, 4 genes, copy number 5: ATAD5, AC130324.2, RNU6-298P, AC130324.1.
- chr21:12,999,676–13,067,033, 3 genes, copy number 6: AP001464.1, ANKRD30BP2, RNU6-614P.

Autosomal genes at a single copy (total copy number 1): 750. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
